Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3522, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3522-01A (Primary Tumor).

*** Diagnosis / Diagnoses: ***

Right hemicolectomy specimen with tumor-free resection margins and under inclusion of an ulcerated, moderately differentiated adenocarcinoma of the ascending colon, exhibiting lymphatic vessel invasion, with infiltration of the perimuscular fatty tissue, and without regional lymph node metastases (G2, pT3 pN0 0/18 L1 V0 R0).

Source: NCI Genomic Data Commons file 381178f8-0faf-4d3c-ad6c-5b55f6900c7d (TCGA-AA-3522.81EC5D87-9F8F-4608-A15A-F015C73CDFA5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).